Somatic mutation profile of tumor specimen 0DS6L5 from CCDI case PBCHMG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.4 years (1,965 days).
Specimen 0DS6L5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 11c6e81b-62ae-4b6e-b748-c5dbe640b022.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DS6LJ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cac87ec2-0727-4c54-a9a7-cc796aa778f2

The open-access MAF lists 6 somatic variants for this specimen: 3 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 3, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PSMC2 | c.343G>A p.V115I | Missense Mutation (SNP) | VAF 24/463 reads (5%) | SIFT tolerated (0.6); PolyPhen benign (0.012); catalogued as COSV53007556; called by muse, mutect2
- TDRD5 | c.152G>T p.R51L | Missense Mutation (SNP) | VAF 24/521 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs755721033, COSV99675509; called by muse, mutect2
- IL11RA | c.268G>A p.G90S | Missense Mutation (SNP) | VAF 29/428 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); called by muse, mutect2
- ARSJ | c.942T>C p.Y314= | Silent (SNP) | VAF 30/560 reads (5%) | catalogued as rs1463223989, COSV59540364; called by muse, mutect2
- CIT | c.4074C>T p.H1358= | Silent (SNP) | VAF 147/451 reads (33%) | called by muse, mutect2, varscan2
- TEX13B | c.108C>T p.F36= | Silent (SNP) | VAF 22/330 reads (7%) | catalogued as rs1282180270, COSV57202353, COSV57203941; called by muse, mutect2
